Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XM-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

Date: _____

Examination: Intraoperative examination

Examination No.: _____

Patient: XXX

PESEL: XXX

Age

Gender: F

Material: Lesion excision – right breast

Unit in charge:

Internal referral

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: 20 minutes (from receipt of material)

Clinical diagnosis: Cancer of the right breast – marked with 1 thread for sternum, 2 threads for the shoulder, 3 threads for the axilla. Please, review the margins.

Examination performed on: _____

Result of intraoperative examination:

Carcinoma invasum mammae 1.1 cm in diameter

Final response to be given after paraffin specimens are analysed

Compliance validated by: _____

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by: _____

Examination performed on: _____

Macroscopic description:

Partial reaction of the mammary gland;

Fragment of the breast sized 6.7 x 5.7 x 3.8 cm with a skin flap of 5.3 x 1.6 cm. We marked typically.

Tumour sized 1.1 x 0.6 x 0.8 cm in the cross section. Margins: 0.8 cm to the base; 1.9 cm to the skin; 3.4 cm to the edge of sternum; 1.8 cm to the axilla, 1.4 cm to the shoulder; 1.3 cm to the lower boundary.

Microscopic description:

Carcinoma ductale invasum mammae dextrae NHG1 (2 + 2 + 1/2 mitoses/10 HPF - visual area of 0.55 mm). The largest dimension of the lesion 1.1 cm. Margins of normal tissues as in the macroscopic description. Glandular tissue showing lesions of the type mastopathia fibrosa partim lipomatosis.

HPA Discrepancy		X

[page 2 of 2]
Examination: Intraoperative examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on:

Histopathology diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast.

NHG1, pT1c, pN0/sn/.

Compliance validated by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file d03f8995-0c6f-41e8-8522-a8956791257b (TCGA-D8-A1XM.7E48315C-3717-40DB-8773-71D070AFC47B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).